Somatic mutation profile of tumor specimen TCGA-ZJ-AAX4-01A (aliquot TCGA-ZJ-AAX4-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAX4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 85.6 years (31,258 days).
Specimen TCGA-ZJ-AAX4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8791d57f-a6c5-4d6b-986b-d6977118e7fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAX4-10B (Blood Derived Normal), aliquot TCGA-ZJ-AAX4-10B-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c79b15d-3fe5-4a51-93ae-f736b38b4ab7

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 40, Silent 19, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.884T>A p.F295Y | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100741847; called by muse, mutect2, varscan2
- ACMSD | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs144757487; called by muse, mutect2
- ACTN2 | c.1606A>G p.M536V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs755708114, COSV100856906; called by muse, mutect2, varscan2
- AFAP1L2 | c.875G>T p.C292F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100412819; called by muse, mutect2, varscan2
- CLASRP | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99673809; called by muse, mutect2, varscan2
- DROSHA | c.3838G>A p.D1280N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100757745; called by muse, mutect2, varscan2
- EXOC4 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV99554903; called by muse, mutect2, varscan2
- FKBP10 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs577855172, COSV99505279; called by muse, mutect2, varscan2
- FLG2 | c.6209G>A p.G2070E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1272633255, COSV101166056; called by muse, mutect2, varscan2
- FOXB1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101249885; called by muse, mutect2, varscan2
- GPR31 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV100834163; called by muse, mutect2, varscan2
- GRIN2B | c.4367T>A p.V1456E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV101663127; called by muse, mutect2, varscan2
- KLRG2 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs752055129, COSV100572459; called by muse, mutect2, varscan2
- LEPR | c.2569C>G p.L857V | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100756706; called by muse, mutect2, varscan2
- LRRIQ3 | c.1646G>T p.S549I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100599080; called by muse, mutect2, varscan2
- MAP1A | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100288995; called by muse, mutect2, varscan2
- MAP3K15 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100135278; called by muse, mutect2, varscan2
- MED12 | c.4070G>A p.R1357H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61332408, COSV61353101; called by muse, mutect2, varscan2
- MYO6 | c.3416G>A p.R1139H (on ENST00000369981; = p.R1129H on NM_004999.4) | Missense Mutation (SNP) | VAF 105/120 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779885818, COSV64119187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.5702G>A p.R1901Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100613983; called by muse, mutect2, varscan2
- OR6C3 | c.524C>A p.A175E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.189); catalogued as COSV101110373; called by muse, mutect2, varscan2
- ORAI1 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs782280709, COSV100345468; called by muse, mutect2, varscan2
- PCARE | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100527747; called by muse, mutect2, varscan2
- PLCL2 | c.2648G>A p.R883Q (on ENST00000615277 / NM_001144382.2; = p.R757Q on NM_015184.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs760913644, COSV101196786; called by muse, mutect2, varscan2
- PRDM9 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.107); catalogued as rs1431161549, COSV57010925, COSV99690866; called by muse, mutect2, varscan2
- PSMD11 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs896609848, COSV99912566; called by muse, mutect2, varscan2
- PYGM | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99377420; called by muse, mutect2, varscan2
- RUNX1T1 | c.1565C>T p.A522V (on ENST00000265814 / NM_001198628.1; = p.A495V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56143042; called by muse, mutect2, varscan2
- SLC25A21 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs745903683, COSV100491964; called by muse, mutect2, varscan2
- SNAPC2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99564259; called by muse, mutect2, varscan2
- SPAG1 | c.2053C>A p.Q685K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.134); catalogued as COSV52560897, COSV99309279; called by muse, mutect2, varscan2
- TAF1A | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100601043, COSV61918321; called by muse, mutect2, varscan2
- TCERG1 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1047211226, COSV99695102; called by muse, mutect2, varscan2
- TMPRSS7 | c.2044G>A p.V682I (on ENST00000452346; = p.V556I on NM_001042575.2) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV101340145; called by muse, mutect2, varscan2
- TRIM65 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs767807385, COSV99485534; called by muse, mutect2, varscan2
- WNK1 | c.2012G>T p.S671I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100268017; called by muse, mutect2
- XRCC5 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV101079751; called by muse, varscan2
- ZNF214 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53482631, COSV53484185; called by muse, mutect2, varscan2
- ZNF280D | c.2726A>G p.D909G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV99974844; called by muse, mutect2, varscan2
- ZNF672 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1057498420, COSV60638490; called by muse, mutect2, varscan2
- EIF3B | c.2141A>G p.Q714R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.07); called by muse, mutect2
- AP2A2 | c.1911C>T p.D637= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs370327293; called by muse, mutect2, varscan2
- ASTN2 | c.2367C>T p.N789= (on ENST00000313400 / NM_001365069.1; = p.N738= on NM_014010.5) | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100529174, COSV57769688; called by muse, mutect2, varscan2
- CEP63 | c.399G>A p.R133= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs1380335963, COSV100132970; called by muse, mutect2, varscan2
- CFAP52 | c.895C>A p.R299= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100235430; called by muse, mutect2, varscan2
- DCTN1 | c.2691C>T p.I897= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100721012; called by muse, mutect2, varscan2
- DPYSL3 | c.171C>T p.T57= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1345295881, COSV100575291; called by muse, mutect2, varscan2
- KAT2A | c.2364G>A p.V788= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV52425293, COSV99288394; called by muse, mutect2, varscan2
- KIF26A | c.5001C>T p.S1667= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs756440739, COSV100181409; called by muse, varscan2
- MYOM2 | c.786G>A p.P262= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1266574442, COSV50701954; called by muse, mutect2, varscan2
- NPHP4 | c.2181T>A p.P727= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100977074, COSV65398505; called by muse, mutect2, varscan2
- OR6C6 | c.372C>T p.I124= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100626505; called by muse, mutect2, varscan2
- PAGR1 | c.352C>T p.L118= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100232743; called by muse, mutect2, varscan2
- RALGDS | c.1005A>G p.L335= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs531903987, COSV100924508; called by muse, mutect2, varscan2
- RPS6KA6 | c.1548G>A p.S516= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV53122060; called by muse, mutect2, varscan2
- SIGLEC1 | c.3939G>A p.V1313= | Silent (SNP) | VAF 50/61 reads (82%) | catalogued as COSV99169832; called by muse, mutect2, varscan2
- SLC4A3 | c.2217C>T p.G739= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs756103529, COSV99813067; called by muse, mutect2, varscan2
- TNC | c.5541G>A p.G1847= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100406074; called by muse, mutect2, varscan2
- VPS33B | c.1614T>C p.D538= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100325690; called by muse, mutect2
- ZNF616 | c.1674C>T p.F558= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100348505; called by muse, mutect2, varscan2
